Somatic mutation profile of tumor specimen ALCH-B36C-TTP1-A (aliquot ALCH-B36C-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B36C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.3 years (24,582 days).
Specimen ALCH-B36C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d844f2c5-6323-4858-a97c-b2505a812778.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36C-NB1-A (Blood Derived Normal), aliquot ALCH-B36C-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a8f01b5-3afd-483a-a10e-904b2bc34e27

The open-access MAF lists 313 somatic variants for this specimen: 217 protein-altering or splice-affecting, 64 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 64, Intron 18, Nonsense Mutation 12, 3'UTR 7, Frame Shift Del 5, RNA 5, Splice Site 4, Splice Region 3, 5'UTR 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 31/338 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.643A>C p.S215R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs142855321; called by muse, mutect2, varscan2
- AIFM1 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54856827, COSV54856953; called by muse, mutect2, varscan2
- AMER1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV57666144; called by muse, mutect2, varscan2
- ATP8A1 | c.793G>T p.G265* | Nonsense Mutation (SNP) | VAF 26/195 reads (13%) | catalogued as COSV52531251; called by muse, mutect2, varscan2
- ATXN10 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 27/421 reads (6%) | catalogued as COSV53294147; called by muse, mutect2
- BLM | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759545027, COSV61925297; called by muse, mutect2, varscan2
- BTK | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CD972098; called by muse, mutect2
- C7 | c.739-1G>C p.X247_splice | Splice Site (SNP) | VAF 12/234 reads (5%) | catalogued as COSV57480182; called by muse, mutect2
- CACNA2D3 | c.2405C>A p.T802K | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as rs755164641; called by muse, mutect2, varscan2
- CDH10 | c.1273C>A p.H425N | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as COSV52572510; called by muse, mutect2, varscan2
- CDKN2A | c.158dup p.M53Ifs*67 | Frame Shift Ins (INS) | VAF 22/65 reads (34%) | catalogued as COSV58720156; called by mutect2, pindel, varscan2
- CEP83 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs201341346; called by muse, mutect2, varscan2
- CHD7 | c.4501G>A p.E1501K | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV71112891; called by muse, mutect2
- CNTN4 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV68564495; called by muse, mutect2
- COL11A1 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as COSV62173347; called by muse, mutect2
- COL1A2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 43/522 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV51954105; called by muse, mutect2
- CTNNA2 | c.75A>T p.E25D | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63577157; called by muse, mutect2, varscan2
- CTNNAL1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.794); catalogued as rs866167967, COSV57701563; called by muse, mutect2
- CYP2W1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs1050340285, COSV100417058; called by muse, mutect2, varscan2
- DCAF12 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV63513361; called by muse, mutect2, varscan2
- DIXDC1 | c.1411C>T p.H471Y (on ENST00000440460 / NM_001037954.4; = p.H260Y on NM_033425.4) | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.656); catalogued as rs369091364; called by muse, mutect2
- DMRT3 | c.1016C>G p.T339R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV51903082, COSV51907025, COSV51909680; called by muse, mutect2, varscan2
- DRC1 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs777645007; called by muse, mutect2, varscan2
- EMB | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100296536; called by muse, mutect2
- FAM122B | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV53232714; called by muse, mutect2, varscan2
- FAM47A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs1426442027, COSV60494190; called by muse, mutect2
- FAT1 | c.6098C>G p.S2033* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV71673625; called by muse, mutect2, varscan2
- FIG4 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs188910818, COSV57788255; ClinVar: uncertain significance; called by muse, mutect2
- GIMAP4 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99750637; called by muse, mutect2
- GPR17 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs755635107, COSV55756400; called by muse, mutect2, varscan2
- GRIA3 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs781446420; called by muse, mutect2, varscan2
- GSN | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369305328; called by muse, mutect2, varscan2
- HEATR5A | c.2891C>T p.S964L | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV66345513; called by muse, mutect2
- HSD17B4 | c.607C>T p.L203F (on ENST00000414835 / NM_001199291.3; = p.L178F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1307944675, COSV56333898; called by muse, mutect2, varscan2
- ICE1 | c.4299G>C p.L1433F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1369755999; called by muse, mutect2, varscan2
- IQCB1 | c.984C>T p.F328= | Splice Region (SNP) | VAF 26/524 reads (5%) | catalogued as rs1331169243, COSV100182101; called by muse, mutect2
- ITGA10 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs142298807; called by muse, mutect2, varscan2
- ITPR3 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs764458886; called by muse, mutect2, varscan2
- KLHL28 | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as COSV61888464; called by muse, mutect2, varscan2
- MANEAL | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61116539; called by muse, mutect2, varscan2
- MED12 | c.4974C>G p.I1658M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.384); catalogued as COSV100378417; called by muse, mutect2, varscan2
- MME | c.-10-1G>T | Splice Site (SNP) | VAF 41/500 reads (8%) | catalogued as rs1085307704, COSV64710172; ClinVar: uncertain significance; called by muse, mutect2
- NLRP13 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV61620997; called by muse, mutect2, varscan2
- NLRP14 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55071295; called by muse, mutect2, varscan2
- NLRP7 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs776575371; called by muse, mutect2, varscan2
- NRG3 | c.1844G>T p.G615V (on ENST00000404547 / NM_001370084.1; = p.G591V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.931); catalogued as rs1267394666, COSV64548311; called by muse, mutect2, varscan2
- OR2T4 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1161549485; called by muse, mutect2, varscan2
- OR8K3 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); catalogued as COSV57132218; called by muse, mutect2, varscan2
- PAX9 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV64062203; called by muse, mutect2, varscan2
- PCDHGA10 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs753942667, COSV53893105; called by muse, mutect2, varscan2
- PGBD1 | c.1840C>A p.L614I | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV52551292, COSV99460385; called by muse, mutect2, varscan2
- PKHD1 | c.6050C>T p.S2017F | Missense Mutation (SNP) | VAF 65/296 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as COSV100581884; called by muse, mutect2, varscan2
- POR | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs781788549; called by muse, mutect2, varscan2
- PPHLN1 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1159959108, COSV99871572; called by muse, mutect2, varscan2
- RASAL1 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV55654282; called by muse, varscan2
- RB1CC1 | c.2590C>G p.Q864E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV50255066; called by muse, mutect2
- RETREG2 | c.419+3G>C | Splice Region (SNP) | VAF 10/154 reads (6%) | catalogued as rs774776092; called by muse, mutect2
- RYR2 | c.4751C>A p.P1584Q | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63682006, COSV63692099; called by muse, mutect2, varscan2
- SCRIB | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1281828169; called by muse, mutect2
- SFRP4 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as COSV99554564; called by muse, mutect2, varscan2
- SHANK3 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761897501; called by muse, mutect2, varscan2
- SLC9A9 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs777449874; called by muse, mutect2
- SYNE1 | c.6205G>A p.D2069N (on ENST00000367255 / NM_182961.4; = p.D2076N on NM_033071.3) | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.093); catalogued as rs1379276899; called by muse, mutect2, varscan2
- TGIF2LX | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV99383180; called by muse, mutect2, varscan2
- TUBA4B | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs538566555, COSV67525437; called by muse, mutect2, varscan2
- UBIAD1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs928829812, COSV65147474; called by muse, mutect2
- USP9X | c.6422G>A p.G2141E | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV61076354; called by muse, mutect2
- ZNF473 | c.2206G>T p.G736W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757488399, COSV99568935; called by muse, mutect2, varscan2
- ABCB4 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- ABCD2 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.116); called by muse, mutect2
- ACAD9 | c.1377A>T p.K459N | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM2B | c.506C>A p.T169K | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ADGRD1 | c.1142C>A p.A381E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADGRG2 | c.2509G>A p.G837S (on ENST00000379869 / NM_001079858.3; = p.G834S on NM_005756.4) | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- AKR1C3 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALS2 | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AMER2 | c.1115T>G p.L372R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMTN | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.5182C>A p.L1728I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ANKRD50 | c.3918A>T p.R1306S | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO5 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- AQP12A | c.124-5T>A | Splice Region (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- ARMH4 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BBIP1 | c.64G>C p.D22H (on ENST00000448814 / NM_001195305.3; = p.R74T on NM_001195304.2) | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); called by muse, mutect2
- BPI | c.476C>A p.P159H (on ENST00000262865; = p.P155H on NM_001725.3) | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BRWD3 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CACNA1F | c.3914A>T p.K1305M | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPZA2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2
- CARD10 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CARM1 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, varscan2
- CASP2 | c.581T>C p.L194S | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CCDC120 | c.1767C>A p.F589L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNB3 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.169); called by muse, mutect2
- CDH12 | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CGB2 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CHRDL1 | c.140A>T p.Y47F (on ENST00000372045; = p.Y53F on NM_145234.4) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- CPA1 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CPSF1 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CTNNA3 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- CUBN | c.6473G>C p.G2158A | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CXXC1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- CXorf58 | c.940-1G>A p.X314_splice | Splice Site (SNP) | VAF 21/202 reads (10%) | called by muse, mutect2, varscan2
- CYLC1 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DAAM2 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCSTAMP | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DEF6 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- DMRT3 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- DNAH6 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DYRK2 | c.1108G>T p.G370C (on ENST00000344096 / NM_006482.3; = p.G297C on NM_003583.4) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF3 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- EPHB1 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ERICH3 | c.1336A>T p.K446* | Nonsense Mutation (SNP) | VAF 58/281 reads (21%) | called by muse, mutect2, varscan2
- ERN1 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- FAM126B | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- FAM135B | c.3709_3711del p.L1237del | In Frame Del (DEL) | VAF 24/195 reads (12%) | called by mutect2, pindel, varscan2
- FAM168A | c.232G>A p.E78K (on ENST00000064778 / NM_001286050.2; = p.E69K on NM_015159.3) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.953); called by muse, mutect2
- FBXO11 | c.269C>G p.S90* (on ENST00000403359 / NM_001190274.2; = p.S6* on NM_025133.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/201 reads (4%) | called by muse, mutect2
- FNBP4 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.115); called by muse, mutect2
- FOXG1 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.466); called by muse, mutect2
- FSTL5 | c.489A>T p.Q163H | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FZD4 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GAS2L2 | c.1922C>A p.A641D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- GCN1 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GPATCH1 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.243); called by muse, mutect2
- HUWE1 | c.11110del p.E3704Sfs*10 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | called by mutect2, pindel, varscan2
- IGHG3 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IGKV1D-42 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.026); called by muse, mutect2
- IGLL1 | c.605C>A p.T202N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- INTU | c.581G>T p.W194L | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- KIAA0753 | c.2719G>C p.E907Q | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.13); called by muse, mutect2
- KIAA1549L | c.3441G>C p.K1147N (on ENST00000321505; = p.K1444N on NM_012194.3) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL42 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- KRT20 | c.48G>C p.L16F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT72 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- L1CAM | c.147del p.T50Qfs*35 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- LILRB1 | c.1466A>T p.Q489L (on ENST00000427581; = p.Q452L on NM_006669.6) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRFN1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.8083A>G p.I2695V | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LRRC52 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MACF1 | c.5923C>G p.H1975D | Missense Mutation (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- MAGED2 | c.1660A>G p.S554G | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K5 | c.448_452del p.A150Tfs*12 | Frame Shift Del (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel, varscan2
- MCF2L | c.336G>C p.Q112H (on ENST00000375608; = p.Q80H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MED30 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- MET | c.4025C>T p.S1342F | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRC1 | c.2030G>T p.R677L | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MRC1 | c.3544G>T p.D1182Y | Missense Mutation (SNP) | VAF 65/465 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MTOR | c.3912G>T p.W1304C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MUC22 | c.4979C>A p.P1660H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC4 | c.7364C>T p.S2455F | Missense Mutation (SNP) | VAF 26/663 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2
- MYH6 | c.1614G>C p.E538D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- N4BP1 | c.1304_1305insCT p.Q435Hfs*6 | Frame Shift Ins (INS) | VAF 56/264 reads (21%) | called by mutect2, varscan2
- NAALAD2 | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.682); called by muse, mutect2
- NBAS | c.12del p.E5Sfs*6 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- NCAM2 | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEB | c.19819C>A p.H6607N | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NECAB2 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NMUR2 | c.1152T>G p.C384W | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.176); called by muse, mutect2
- NOS1 | c.3293C>A p.A1098D | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRG3 | c.1843G>T p.G615W (on ENST00000404547 / NM_001370084.1; = p.G591W on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR2L8 | c.731T>A p.L244H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2M7 | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR8K5 | c.475T>C p.F159L | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2
- PATZ1 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); called by muse, mutect2
- PCCB | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PCDH19 | c.3176G>T p.C1059F (on ENST00000373034 / NM_001184880.2; = p.C1011F on NM_020766.3) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.36); called by muse, varscan2
- PDZD4 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, varscan2
- POTEF | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PRDM9 | c.109A>C p.K37Q | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRKAG2 | c.1364G>C p.R455T | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- PRKG2 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PRTFDC1 | c.554-1G>A p.X185_splice | Splice Site (SNP) | VAF 55/220 reads (25%) | called by muse, mutect2, varscan2
- PRUNE2 | c.4613G>T p.S1538I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- RFX5 | c.1012C>A p.R338S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RGPD4 | c.5077G>A p.E1693K | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- RNF20 | c.1947G>T p.M649I | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SERPINB3 | c.483C>A p.N161K | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SERPINB7 | c.960G>C p.R320S | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SHOX | c.687C>A p.H229Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SHOX | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- SLITRK3 | c.2408A>G p.E803G | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRPK1 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.447); called by muse, mutect2
- STARD13 | c.2170G>A p.E724K (on ENST00000336934 / NM_001243476.3; = p.E606K on NM_052851.3) | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); called by muse, mutect2
- SYNE1 | c.11270T>G p.M3757R (on ENST00000367255 / NM_182961.4; = p.M3742R on NM_033071.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- TAS2R60 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TBATA | c.62T>A p.L21Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TEP1 | c.793A>T p.T265S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.1565A>T p.K522M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.05); called by muse, varscan2
- TKTL2 | c.1703G>T p.R568M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); called by muse, mutect2
- TMF1 | c.1065A>C p.L355F | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- TOR1AIP1 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- TRRAP | c.5369G>T p.G1790V (on ENST00000359863 / NM_001244580.1; = p.G1772V on NM_003496.3) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.068); called by muse, mutect2
- TTLL5 | c.3729G>C p.Q1243H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTN | c.14359T>C p.F4787L (on ENST00000591111; = p.F3860L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | PolyPhen probably damaging (0.987); called by muse, mutect2
- UBE2F | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- UNC5B | c.2082del p.L695Sfs*28 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- UNC79 | c.6764A>G p.K2255R (on ENST00000393151 / NM_001346218.2; = p.K2078R on NM_020818.5) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UPF3B | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- USP40 | c.2608G>C p.D870H | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- WDR17 | c.3014A>T p.H1005L | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2
- WDR18 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- WWC3 | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- XIAP | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPNPEP2 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XPNPEP2 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- YIF1B | c.107A>G p.H36R (on ENST00000339413 / NM_001039673.3; = p.H21R on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, varscan2
- ZNF189 | c.1747C>G p.L583V | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF345 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF345 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF438 | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.359); called by muse, mutect2
- ZNF551 | c.1532C>A p.S511Y | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ZNF555 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- ZNF597 | c.894C>A p.H298Q | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2
- ZNF846 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2
- ALG13 | c.33C>T p.T11= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- ANKRD18A | c.2157T>C p.N719= | Silent (SNP) | VAF 28/178 reads (16%) | catalogued as rs1228961863; called by muse, mutect2, varscan2
- ARHGEF12 | c.1800C>T p.I600= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- AS3MT | c.519G>T p.R173= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV54915429; called by muse, mutect2, varscan2
- ASS1 | c.1227C>T p.V409= | Silent (SNP) | VAF 30/263 reads (11%) | catalogued as rs923451802, COSV61688555; called by muse, mutect2, varscan2
- ATP1B4 | c.993G>A p.L331= (on ENST00000218008 / NM_001142447.3; = p.L327= on NM_012069.5) | Silent (SNP) | VAF 18/185 reads (10%) | called by muse, mutect2
- CDK5RAP2 | c.3870G>T p.V1290= | Silent (SNP) | VAF 41/224 reads (18%) | catalogued as rs770602220, COSV62575161; called by muse, mutect2, varscan2
- CHAT | c.441G>T p.L147= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- COL11A1 | c.3225G>T p.G1075= | Silent (SNP) | VAF 33/303 reads (11%) | called by muse, mutect2, varscan2
- COL13A1 | c.687G>T p.L229= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs753169606; called by muse, mutect2, varscan2
- CRB2 | c.2649C>T p.S883= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs930743090; called by muse, mutect2
- CSMD3 | c.8799T>C p.C2933= (on ENST00000297405 / NM_001363185.1; = p.C2764= on NM_052900.3) | Silent (SNP) | VAF 13/182 reads (7%) | called by muse, mutect2
- FAM47A | c.1914C>A p.T638= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV100650021; called by mutect2, varscan2
- FLT3 | c.498C>T p.Y166= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99607693; called by muse, mutect2
- GALR1 | c.771A>T p.G257= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV55315971; called by muse, mutect2
- GUSB | c.528C>T p.L176= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- H1-7 | c.456G>A p.R152= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV58602498; called by muse, mutect2, varscan2
- HDAC7 | c.108C>T p.G36= (on ENST00000427332; = p.G75= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2
- IAH1 | c.699A>T p.V233= | Silent (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- IL18R1 | c.1542G>A p.K514= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV52126670; called by muse, mutect2, varscan2
- IL4R | c.415C>T p.L139= | Silent (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
- INSM2 | c.1410C>T p.F470= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs756436213; called by muse, mutect2, varscan2
- ITGA8 | c.2913G>T p.L971= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- ITPR3 | c.7467C>G p.L2489= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- LCN6 | c.384C>T p.D128= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs141136161; called by muse, mutect2, varscan2
- MRGPRX2 | c.261G>T p.L87= | Silent (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- MTUS2 | c.1275G>A p.R425= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2, varscan2
- MUC5AC | c.912C>A p.L304= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- MYH10 | c.5553G>C p.L1851= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV52602109; called by muse, mutect2
- NEO1 | c.513G>C p.L171= | Silent (SNP) | VAF 26/215 reads (12%) | called by muse, mutect2, varscan2
- NEUROG3 | c.171C>A p.A57= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1229709730; called by muse, mutect2
- NUDC | c.537G>A p.S179= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs765242799, COSV100345537, COSV58326401; called by muse, mutect2, varscan2
- OR10P1 | c.396C>T p.R132= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- OR51G1 | c.162T>C p.D54= | Silent (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- OR52E6 | c.270T>C p.N90= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV61433213; called by muse, mutect2, varscan2
- OR6F1 | c.501C>T p.S167= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100128939, COSV57467244; called by muse, mutect2, varscan2
- OR8H2 | c.843G>T p.V281= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as COSV57943516; called by muse, mutect2
- P2RY14 | c.117C>G p.L39= | Silent (SNP) | VAF 59/504 reads (12%) | called by muse, mutect2, varscan2
- PCDH19 | c.3045C>T p.F1015= (on ENST00000373034 / NM_001184880.2; = p.F967= on NM_020766.3) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs746702101, COSV55261491; called by muse, varscan2
- PCDHA2 | c.2040G>A p.S680= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1554120239; called by muse, mutect2, varscan2
- PQBP1 | c.424C>A p.R142= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, varscan2
- RAB39B | c.123G>T p.V41= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs137950464, COSV65624509; called by muse, mutect2, varscan2
- RADIL | c.3165C>T p.F1055= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- RNF39 | c.384C>A p.P128= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- ROBO2 | c.2688G>T p.T896= | Silent (SNP) | VAF 53/206 reads (26%) | catalogued as COSV59897272; called by muse, mutect2, varscan2
- SELENOV | c.378C>G p.A126= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- SGSM1 | c.483G>C p.L161= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV68511663; called by muse, mutect2
- SHANK1 | c.2214G>T p.V738= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- SLC19A2 | c.61C>A p.R21= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- SUMO4 | c.222A>T p.A74= | Silent (SNP) | VAF 36/201 reads (18%) | called by muse, mutect2, varscan2
- SYNC | c.964C>A p.R322= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- TNXB | c.8673C>T p.L2891= (on ENST00000647633; = p.L2644= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs779020364; called by muse, mutect2, varscan2
- TRRAP | c.6867G>A p.L2289= (on ENST00000359863 / NM_001244580.1; = p.L2271= on NM_003496.3) | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV62850369; called by muse, mutect2
- TTLL11 | c.1407C>T p.G469= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs535244895; called by muse, mutect2, varscan2
- UNC13C | c.4305C>T p.P1435= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as rs376495525; called by muse, mutect2
- WDR70 | c.846T>C p.H282= | Silent (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- ZBBX | c.1530T>C p.N510= | Silent (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- ZFP92 | c.879C>A p.A293= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- ZMAT1 | c.1818C>T p.S606= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as rs542584730, COSV65659027; called by muse, mutect2
- ZNF385B | c.252G>A p.Q84= | Silent (SNP) | VAF 14/85 reads (16%) | called by mutect2, varscan2
- ZNF462 | c.1008C>T p.S336= | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- ZNF630 | c.813C>A p.A271= | Silent (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- ZNF721 | c.672G>A p.L224= (on ENST00000338977; = p.L236= on NM_133474.4) | Silent (SNP) | VAF 24/175 reads (14%) | catalogued as rs192018843; called by muse, mutect2, varscan2
- ZNF765 | c.1086G>A p.K362= | Silent (SNP) | VAF 16/524 reads (3%) | called by muse, mutect2
- AL136982.4 | n.573G>A | RNA (SNP) | VAF 24/388 reads (6%) | called by muse, mutect2
- C3 | c.3646+19G>T | Intron (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- CCDC24 | c.-56G>A | 5'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- CCDC69 | c.*23C>A | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- CEP41 | c.*1074G>T | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- CHST13 | c.97+4830A>G | Intron (SNP) | VAF 16/119 reads (13%) | catalogued as rs1184523963; called by muse, mutect2, varscan2
- COL22A1 | c.1758+64C>T | Intron (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- CPLX4 | c.*57G>T | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- CYP11B2 | c.*7A>T | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by mutect2, varscan2
- EGFEM1P | n.596G>A | RNA (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- ERGIC3 | c.*8C>T | 3'UTR (SNP) | VAF 5/38 reads (13%) | catalogued as rs746274357, COSV99481846; called by muse, mutect2
- FHAD1 | c.4122+1737C>A | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- GABRA3 | c.-26-29892C>A | Intron (SNP) | VAF 27/195 reads (14%) | called by muse, mutect2, varscan2
- GPAA1 | c.75-22G>T | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as rs782515469; called by muse, mutect2, varscan2
- GYPA | c.136+36G>A | Intron (SNP) | VAF 35/130 reads (27%) | catalogued as rs777745115; called by muse, mutect2, varscan2
- GZMK | c.-59C>T | 5'UTR (SNP) | VAF 16/401 reads (4%) | called by muse, mutect2
- IGFN1 | c.1241+627G>A | Intron (SNP) | VAF 10/101 reads (10%) | catalogued as COSV55166835; called by muse, mutect2, varscan2
- L1CAM | c.1546+39G>T | Intron (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99055188; called by muse, mutect2, varscan2
- LIPH | c.49+5485C>G | Intron (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- LUC7L3 | c.*33+123A>T | Intron (SNP) | VAF 77/248 reads (31%) | called by muse, mutect2, varscan2
- MBTPS2 | c.*20G>A | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- MKRN9P | n.261G>T | RNA (SNP) | VAF 27/125 reads (22%) | called by muse, mutect2, varscan2
- MRGPRF | c.48+80C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as COSV57996470; called by muse, mutect2, varscan2
- NAALAD2 | c.1278+62G>T | Intron (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- PAX6 | c.1032+59C>T | Intron (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- PPFIA2 | c.303+78794C>A | Intron (SNP) | VAF 54/324 reads (17%) | called by muse, mutect2, varscan2
- PRDM5 | c.743+12G>C | Intron (SNP) | VAF 41/319 reads (13%) | catalogued as rs1435671695; called by muse, mutect2, varscan2
- SLC43A2 | c.*13C>T | 3'UTR (SNP) | VAF 22/59 reads (37%) | catalogued as rs1402889027; called by muse, mutect2, varscan2
- SLC7A5P1 | n.445G>T | RNA (SNP) | VAF 31/167 reads (19%) | catalogued as rs756732247; called by muse, mutect2, varscan2
- TAPT1 | c.450-5197G>A | Intron (SNP) | VAF 34/290 reads (12%) | catalogued as rs1435606332; called by muse, mutect2, varscan2
- TCFL5 | c.1381-3997C>T | Intron (SNP) | VAF 5/47 reads (11%) | catalogued as rs1207746500; called by muse, mutect2, varscan2
- TMEM183B | n.148G>A | RNA (SNP) | VAF 12/162 reads (7%) | catalogued as rs529964693; called by muse, mutect2
